Gene-level copy-number profile of tumor specimen C3L-09082-05 from CPTAC case C3L-09082, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 68.4 years (24,977 days).
Specimen C3L-09082-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4b6f49f4-9755-47dd-bca0-57af238a4970.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09082-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/0b688d8e-cde1-40e1-a99c-e08ae80c5e82

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 531; copy number 1: 704; copy number 2: 8,666; copy number 3: 19,014; copy number 4: 19,315; copy number 5: 5,479; copy number 6: 1,565; copy number 7: 1,810; copy number 8: 1,362; copy number 9: 430; copy number 10: 10; copy number 11: 7.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–4): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–3): AC104164.2, MIR548BB.
- chr11:90,251,204–90,915,052, 5 genes (within-gene range 0–4): DISC1FP1, TUBAP2, MIR4490, AP002782.1, MIR1261.
- chr16:78,355,529–78,506,568, 2 genes (within-gene range 0–4): LSM3P5, AC046158.1.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–5): RPS10P2.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–5): AL138808.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 447 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–12,947,580, 1 gene, copy number 11 (within-gene range 7–11): PRAMEF6.
- chr11:42,939,775–50,422,316, 223 genes, copy number 9 (broad region; genes not listed).
- chr13:21,483,834–23,170,597, 24 genes, copy number 9: H2BP6, MICU2, FNTAP2, RNU6-59P, RPS7P10, FGF9, RN7SL766P, LINC00424, LINC00540, NME1P1, MTND3P1, FTH1P7, DDX39AP1, SNORD36, RPL7AP73, IPMKP1, RFESDP1, LINC00621, BASP1P1, NUS1P2, AL157931.1, HMGA1P6, RNY3P4, LINC00362.
- chr13:47,745,736–48,037,968, 1 gene, copy number 9 (within-gene range 5–9): SUCLA2.
- chr13:47,825,330–48,599,436, 21 genes, copy number 9 (within-gene range 7–9): AL138962.1, LINC00562, AL157369.1, SUCLA2-AS1, NUDT15, AL158196.1, MED4, MED4-AS1, POLR2KP2, ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077.
- chr13:55,535,697–56,000,448, 2 genes, copy number 9: AL354821.1, HNF4GP1.
- chr13:76,880,175–77,019,143, 7 genes, copy number 9: KCTD12, AC000403.1, BTF3P11, ACOD1, RPL7P44, DHX9P1, CLN5.
- chr13:76,992,598–77,027,195, 1 gene, copy number 9: FBXL3.
- chr13:77,027,944–77,028,482, 1 gene, copy number 9: AC001226.1.
- chr13:108,207,439–109,808,252, 18 genes, copy number 9: LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1.
- chr19:41,088,451–41,307,787, 10 genes, copy number 10 (within-gene range 6–10): CYP2A13, CYP2F1, CYP2T3P, RPL36P16, RN7SL718P, CYP2S1, AXL, AC011510.1, HNRNPUL1, RN7SL34P.
- chr20:5,318,268–5,503,189, 1 gene, copy number 9 (within-gene range 8–9): AL121757.2.
- chr20:5,426,892–13,996,443, 111 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr20:32,186,477–32,355,734, 6 genes, copy number 11: TSPY26P, PLAGL2, POFUT1, MIR1825, KIF3B, AL121583.1.
- chr20:62,302,093–62,577,507, 20 genes, copy number 9: ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1.

Autosomal genes at a single copy (total copy number 1): 704. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
